Somatic mutation profile of tumor specimen TCGA-61-1734-01B (aliquot TCGA-61-1734-01B-01W-0722-08) from TCGA case TCGA-61-1734, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IC; Tumor grade: G3; Age at diagnosis: 52.1 years (19,026 days).
Specimen TCGA-61-1734-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2193c835-6d6a-475e-b686-480c7a81369a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-1734-11A (Solid Tissue Normal), aliquot TCGA-61-1734-11A-01W-0722-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3cdcf30-cf44-45a6-8617-f0d2d6e89118

The open-access MAF lists 378 somatic variants for this specimen: 352 protein-altering or splice-affecting, 10 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Frame Shift Ins 301, Missense Mutation 38, Silent 10, Intron 6, Splice Site 6, Nonsense Mutation 4, RNA 3, 5'Flank 3, 5'UTR 2, Frame Shift Del 2, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA1 | c.5345G>A p.W1782* | Nonsense Mutation (SNP) | VAF 44/65 reads (68%) | catalogued as rs80357219, CM032199; ClinVar: pathogenic; called by muse, varscan2
- AK9 | c.590dup p.E198Rfs*24 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | catalogued as COSV99572707; called by mutect2, varscan2
- AKAP12 | c.3790A>T p.T1264S | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as rs1330911023; called by mutect2, varscan2
- ASF1B | c.436dup p.V146Gfs*51 | Frame Shift Ins (INS) | VAF 4/46 reads (9%) | catalogued as rs749689410; called by mutect2, pindel
- BCHE | c.1628G>C p.R543P | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV100013055; called by mutect2, varscan2
- CCDC73 | c.3193A>T p.K1065* | Nonsense Mutation (SNP) | VAF 10/29 reads (34%) | catalogued as COSV58800216; called by mutect2, varscan2
- CLEC18B | c.516G>T p.Q172H | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.833); catalogued as COSV60576274; called by mutect2, varscan2
- KBTBD3 | c.1269T>A p.D423E | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT tolerated (1); PolyPhen benign (0.354); catalogued as rs747838631; called by muse, mutect2, varscan2
- LRP4 | c.1123dup p.A375Gfs*24 | Frame Shift Ins (INS) | VAF 6/30 reads (20%) | catalogued as rs777522999; called by pindel, varscan2
- MYOZ3 | c.623dup p.T209Hfs*36 | Frame Shift Ins (INS) | VAF 6/51 reads (12%) | catalogued as rs766492573; called by pindel, varscan2
- NALCN | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 68/182 reads (37%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.793); catalogued as rs549926959, COSV51923120, COSV51930613; called by mutect2, varscan2
- OR51L1 | c.856C>A p.P286T | Missense Mutation (SNP) | VAF 68/91 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV58624046; called by mutect2, varscan2
- OR5H14 | c.919dup p.R307Kfs*3 | Frame Shift Ins (INS) | VAF 5/52 reads (10%) | catalogued as rs1316045711; called by mutect2, pindel
- OR5I1 | c.579C>A p.D193E | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.389); catalogued as rs754002853, COSV99041734; called by mutect2, varscan2
- PCDHA11 | c.1129G>C p.D377H | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56518578; called by mutect2, varscan2
- PRDM1 | c.1148C>T p.T383M | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.346); catalogued as rs548489075, COSV64846037; ClinVar: not provided; called by mutect2, varscan2
- SOS1 | c.3355A>G p.T1119A | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs764640296, COSV67674101; called by mutect2, varscan2
- SS18 | c.647A>G p.N216S | Missense Mutation (SNP) | VAF 123/530 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.014); catalogued as rs778157911; called by mutect2, varscan2
- TONSL | c.1864dup p.A622Gfs*67 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | catalogued as rs762903420; called by pindel, varscan2
- TP53 | c.80del p.P27Lfs*17 | Frame Shift Del (DEL) | VAF 21/50 reads (42%) | catalogued as rs1192416464, COSV53662521; called by mutect2, pindel, varscan2
- TRIOBP | c.3304dup p.Q1102Pfs*82 | Frame Shift Ins (INS) | VAF 3/33 reads (9%) | catalogued as rs747966150; called by pindel, varscan2
- UFL1 | c.2263A>G p.N755D | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748350583; called by mutect2, varscan2
- VIT | c.1447C>T p.R483C (on ENST00000389975 / NM_001177969.1; = p.R498C on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs141665993; called by mutect2, varscan2
- AAK1 | c.887dup p.D297Rfs*3 | Frame Shift Ins (INS) | VAF 3/30 reads (10%) | called by mutect2, pindel
- ABCC3 | c.3802_3803insG p.T1268Sfs*79 | Frame Shift Ins (INS) | VAF 3/31 reads (10%) | called by mutect2, pindel
- ABLIM2 | c.644dup p.C215Wfs*2 | Frame Shift Ins (INS) | VAF 3/20 reads (15%) | called by mutect2, pindel
- AC004593.2 | c.383dup p.Y130Ifs*17 | Frame Shift Ins (INS) | VAF 3/21 reads (14%) | called by mutect2, pindel
- ACVR2A | c.5dup p.A3_?2 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, varscan2
- ADAMTS6 | c.2795C>T p.P932L | Missense Mutation (SNP) | VAF 200/282 reads (71%) | SIFT tolerated (0.39); PolyPhen benign (0.103); called by mutect2, varscan2
- ADGRV1 | c.5482G>A p.D1828N | Missense Mutation (SNP) | VAF 63/88 reads (72%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ADGRV1 | c.18321dup p.I6108Dfs*105 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel
- AHNAK | c.5742_5743insTGAG p.M1915* | Nonsense Mutation (INS) | VAF 35/179 reads (20%) | called by pindel, varscan2
- AHNAK2 | c.2823dup p.K942Qfs*104 | Frame Shift Ins (INS) | VAF 6/38 reads (16%) | called by mutect2, varscan2
- AKAP8 | c.1915_1916insC p.V639Afs*7 | Frame Shift Ins (INS) | VAF 5/41 reads (12%) | called by mutect2, pindel
- AKAP9 | c.329C>G p.T110R | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ALDH1L1 | c.1661dup p.N555Qfs*70 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel
- ANKLE2 | c.1847dup p.G617Rfs*10 | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | called by mutect2, pindel, varscan2
- ANO1 | c.1610dup p.I538Hfs*66 | Frame Shift Ins (INS) | VAF 3/27 reads (11%) | called by mutect2, pindel
- AOC1 | c.1626dup p.W543Lfs*33 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by mutect2, pindel, varscan2
- APLP2 | c.793dup p.E265Gfs*12 | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | called by pindel, varscan2
- ARHGEF11 | c.3277dup p.H1093Pfs*24 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by mutect2, pindel, varscan2
- ARID3C | c.265dup p.Q89Pfs*21 | Frame Shift Ins (INS) | VAF 3/30 reads (10%) | called by mutect2, pindel
- ASIC2 | c.585_586insC p.F196Lfs*2 | Frame Shift Ins (INS) | VAF 3/25 reads (12%) | called by mutect2, pindel
- ASIP | c.181dup p.Q61Pfs*14 | Frame Shift Ins (INS) | VAF 4/48 reads (8%) | called by mutect2, pindel
- ASPM | c.5027dup p.L1676Ffs*15 | Frame Shift Ins (INS) | VAF 6/60 reads (10%) | called by pindel, varscan2
- ASTN1 | c.1618dup p.E540Gfs*69 | Frame Shift Ins (INS) | VAF 4/41 reads (10%) | called by mutect2, pindel
- ASXL2 | c.2967dup p.M990Dfs*13 | Frame Shift Ins (INS) | VAF 6/42 reads (14%) | called by mutect2, varscan2
- ATG4A | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 118/287 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.06); called by mutect2, varscan2
- ATP2A2 | c.1989dup p.A664Rfs*16 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by mutect2, pindel, varscan2
- ATXN10 | c.208dup p.Q70Pfs*44 | Frame Shift Ins (INS) | VAF 6/61 reads (10%) | called by mutect2, varscan2
- ATXN2 | c.741dup p.S248Qfs*2 (on ENST00000550104; = p.S88Qfs*2 on NM_002973.4) | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by mutect2, pindel
- AVPR1B | c.783dup p.L262Afs*51 | Frame Shift Ins (INS) | VAF 6/52 reads (12%) | called by pindel, varscan2
- BAHD1 | c.2055dup p.Q687Afs*3 | Frame Shift Ins (INS) | VAF 4/39 reads (10%) | called by mutect2, pindel
- BAP1 | c.1332dup p.I445Hfs*6 | Frame Shift Ins (INS) | VAF 3/31 reads (10%) | called by mutect2, pindel
- BAZ1A | c.1145dup p.E383* | Frame Shift Ins (INS) | VAF 3/34 reads (9%) | called by mutect2, pindel
- BCAR1 | c.1853dup p.G619Wfs*9 | Frame Shift Ins (INS) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- BCL9L | c.1478dup p.G495Wfs*22 | Frame Shift Ins (INS) | VAF 4/44 reads (9%) | called by pindel, varscan2
- BOLA1 | c.350dup p.N117Kfs*7 | Frame Shift Ins (INS) | VAF 3/26 reads (12%) | called by mutect2, pindel
- BPTF | c.4549dup p.E1517Gfs*6 | Frame Shift Ins (INS) | VAF 3/27 reads (11%) | called by mutect2, pindel
- BSPRY | c.966dup p.F323Lfs*9 | Frame Shift Ins (INS) | VAF 6/68 reads (9%) | called by mutect2, pindel
- C6orf118 | c.312dup p.M105Dfs*18 | Frame Shift Ins (INS) | VAF 4/33 reads (12%) | called by mutect2, pindel
- CA11 | c.735dup p.C246Lfs*11 | Frame Shift Ins (INS) | VAF 5/36 reads (14%) | called by pindel, varscan2
- CACNA1E | c.1708dup p.V570Gfs*12 | Frame Shift Ins (INS) | VAF 3/24 reads (13%) | called by mutect2, pindel
- CACNA1F | c.1789dup p.D597Gfs*38 | Frame Shift Ins (INS) | VAF 3/31 reads (10%) | called by mutect2, pindel
- CAPN2 | c.1326dup p.Q443Afs*62 | Frame Shift Ins (INS) | VAF 5/50 reads (10%) | called by pindel, varscan2
- CAPN9 | c.510dup p.A171Rfs*15 | Frame Shift Ins (INS) | VAF 4/37 reads (11%) | called by mutect2, varscan2
- CARMIL3 | c.2632dup p.D878Gfs*12 | Frame Shift Ins (INS) | VAF 5/50 reads (10%) | called by mutect2, pindel, varscan2
- CCDC116 | c.359dup p.G121Wfs*42 | Frame Shift Ins (INS) | VAF 5/28 reads (18%) | called by pindel, varscan2
- CCDC7 | c.2620dup p.Q874Pfs*16 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by pindel, varscan2
- CCNJL | c.994dup p.A332Gfs*69 | Frame Shift Ins (INS) | VAF 3/29 reads (10%) | called by mutect2, pindel
- CCR6 | c.753dup p.A252Sfs*20 | Frame Shift Ins (INS) | VAF 4/29 reads (14%) | called by mutect2, pindel, varscan2
- CD163L1 | c.2379G>T p.R793S | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.581); called by mutect2, varscan2
- CD2BP2 | c.443dup p.Q149Pfs*20 | Frame Shift Ins (INS) | VAF 5/46 reads (11%) | called by mutect2, pindel
- CDH24 | c.1069_1070insT p.D357Vfs*29 | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | called by mutect2, pindel
- CDK1 | c.36dup p.G13Rfs*8 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | called by mutect2, pindel
- CDKL5 | c.2291dup p.N764Kfs*3 | Frame Shift Ins (INS) | VAF 4/35 reads (11%) | called by mutect2, pindel
- CEP350 | c.4027dup p.V1343Gfs*11 | Frame Shift Ins (INS) | VAF 4/24 reads (17%) | called by mutect2, pindel
- CHM | c.1404dup p.D469Rfs*23 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by mutect2, pindel
- CHPF | c.1450dup p.R484Pfs*21 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by mutect2, pindel
- CHRNB2 | c.109dup p.L37Pfs*18 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by pindel, varscan2
- CHST12 | c.608dup p.R204Afs*191 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by pindel, varscan2
- CHST5 | c.1089dup p.I364Dfs*28 | Frame Shift Ins (INS) | VAF 3/24 reads (13%) | called by mutect2, pindel
- CLDN14 | c.565dup p.A189Gfs*93 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by mutect2, pindel
- CLDN18 | c.25dup p.V9Gfs*138 | Frame Shift Ins (INS) | VAF 4/42 reads (10%) | called by pindel, varscan2
- CMKLR1 | c.1044dup p.S349Qfs*3 (on ENST00000312143 / NM_001142344.2; = p.S347Qfs*3 on NM_004072.3) | Frame Shift Ins (INS) | VAF 4/46 reads (9%) | called by mutect2, pindel
- COL12A1 | c.8488G>C p.G2830R | Missense Mutation (SNP) | VAF 34/45 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COQ6 | c.130G>A p.G44S | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CSTB | c.237dup p.T81Dfs*4 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by pindel, varscan2
- CUX1 | c.3069dup p.P1024Afs*35 | Frame Shift Ins (INS) | VAF 4/35 reads (11%) | called by pindel, varscan2
- CXCL16 | c.343dup p.H115Pfs*55 | Frame Shift Ins (INS) | VAF 3/24 reads (13%) | called by mutect2, pindel
- CXCR3 | c.554dup p.D186Rfs*174 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by pindel, varscan2
- DBX2 | c.536dup p.N180* | Frame Shift Ins (INS) | VAF 3/29 reads (10%) | called by mutect2, pindel
- DGKK | c.2530dup p.H844Pfs*5 | Frame Shift Ins (INS) | VAF 3/33 reads (9%) | called by mutect2, pindel
- DLGAP4 | c.638dup p.E214Rfs*50 | Frame Shift Ins (INS) | VAF 4/31 reads (13%) | called by mutect2, pindel, varscan2
- DLGAP4 | c.2628dup p.T877Hfs*25 (on ENST00000339266 / NM_001365621.1; = p.T874Hfs*25 on NM_014902.6) | Frame Shift Ins (INS) | VAF 4/46 reads (9%) | called by mutect2, pindel
- DNAJB5 | c.509dup p.V171Sfs*30 | Frame Shift Ins (INS) | VAF 3/19 reads (16%) | called by pindel, varscan2
- DOK3 | c.557dup p.D187Rfs*35 | Frame Shift Ins (INS) | VAF 4/23 reads (17%) | called by pindel, varscan2
- DUOX2 | c.1283G>A p.S428N | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.021); called by muse, varscan2
- DYSF | c.3776dup p.L1260Tfs*16 | Frame Shift Ins (INS) | VAF 5/35 reads (14%) | called by mutect2, pindel, varscan2
- E2F4 | c.611dup p.V205Cfs*9 | Frame Shift Ins (INS) | VAF 6/47 reads (13%) | called by mutect2, varscan2
- EDAR | c.656-3dup | Splice Region (INS) | VAF 6/55 reads (11%) | called by mutect2, pindel
- ELAPOR1 | c.230dup p.L78Pfs*7 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by pindel, varscan2
- EMC1 | c.400dup p.V134Gfs*38 | Frame Shift Ins (INS) | VAF 4/31 reads (13%) | called by pindel, varscan2
- EML4 | c.2794dup p.E932Gfs*4 | Frame Shift Ins (INS) | VAF 4/41 reads (10%) | called by pindel, varscan2
- ENTPD5 | c.131dup p.S44Rfs*11 | Frame Shift Ins (INS) | VAF 6/42 reads (14%) | called by mutect2, pindel, varscan2
- EPB41L4A | c.894dup p.E299Rfs*3 | Frame Shift Ins (INS) | VAF 3/25 reads (12%) | called by mutect2, pindel
- EPHB4 | c.2089dup p.E697Gfs*62 | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | called by mutect2, pindel
- EPS8L1 | c.1452dup p.C485Vfs*2 (on ENST00000201647 / NM_133180.3; = p.C358Vfs*2 on NM_017729.3) | Frame Shift Ins (INS) | VAF 4/44 reads (9%) | called by mutect2, pindel
- ESAM | c.928dup p.L310Pfs*90 | Frame Shift Ins (INS) | VAF 4/31 reads (13%) | called by pindel, varscan2
- ESCO1 | c.1397dup p.N466Kfs*2 | Frame Shift Ins (INS) | VAF 4/27 reads (15%) | called by pindel, varscan2
- ESRP1 | c.1960dup p.Q654Pfs*16 | Frame Shift Ins (INS) | VAF 5/43 reads (12%) | called by mutect2, pindel, varscan2
- ESYT1 | c.2727dup p.L910Afs*15 | Frame Shift Ins (INS) | VAF 4/24 reads (17%) | called by mutect2, pindel
- ETNK2 | c.562_563insC p.N188Tfs*34 | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | called by mutect2, pindel, varscan2
- FAM83F | c.696dup p.M233Hfs*20 | Frame Shift Ins (INS) | VAF 3/32 reads (9%) | called by mutect2, pindel
- FBLN1 | c.1626dup p.F543Lfs*16 | Frame Shift Ins (INS) | VAF 3/28 reads (11%) | called by mutect2, pindel
- FBXO42 | c.2105A>T p.K702M | Missense Mutation (SNP) | VAF 100/135 reads (74%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- FHL3 | c.191dup p.C65Lfs*14 | Frame Shift Ins (INS) | VAF 4/47 reads (9%) | called by pindel, varscan2
- FLNC | c.7469dup p.S2490Rfs*54 | Frame Shift Ins (INS) | VAF 4/20 reads (20%) | called by mutect2, pindel, varscan2
- FLT4 | c.3085dup p.A1029Gfs*27 | Frame Shift Ins (INS) | VAF 3/22 reads (14%) | called by mutect2, pindel
- FNTB | c.1110_1111insC p.S371Lfs*14 | Frame Shift Ins (INS) | VAF 3/34 reads (9%) | called by mutect2, pindel
- FOXR1 | c.760_761insG p.T254Sfs*38 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel
- FXR2 | c.786dup p.I263Hfs*2 | Frame Shift Ins (INS) | VAF 3/29 reads (10%) | called by mutect2, pindel
- GANAB | c.1160dup p.L388Vfs*21 | Frame Shift Ins (INS) | VAF 3/26 reads (12%) | called by mutect2, pindel
- GGT7 | c.1498dup p.L500Pfs*24 | Frame Shift Ins (INS) | VAF 3/23 reads (13%) | called by mutect2, pindel
- GINS1 | c.16dup p.A6Gfs*36 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, varscan2
- GON4L | c.4678dup p.A1560Gfs*4 | Frame Shift Ins (INS) | VAF 3/31 reads (10%) | called by mutect2, pindel
- GPCPD1 | c.1584_1585insG p.S529Vfs*2 | Frame Shift Ins (INS) | VAF 4/49 reads (8%) | called by mutect2, pindel
- GPN2 | c.428dup p.V144Rfs*41 | Frame Shift Ins (INS) | VAF 3/26 reads (12%) | called by mutect2, pindel
- GPR37L1 | c.526dup p.D176Gfs*25 | Frame Shift Ins (INS) | VAF 4/47 reads (9%) | called by mutect2, pindel
- GPR85 | c.930dup p.A311Cfs*66 | Frame Shift Ins (INS) | VAF 5/38 reads (13%) | called by mutect2, pindel
- GTSF1 | c.371dup p.H125Sfs*4 | Frame Shift Ins (INS) | VAF 3/36 reads (8%) | called by mutect2, pindel
- GUCY2D | c.836A>C p.D279A | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- GYS1 | c.1738dup p.R580Pfs*79 | Frame Shift Ins (INS) | VAF 3/34 reads (9%) | called by mutect2, pindel
- HECW2 | c.1430dup p.Y478Lfs*15 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by pindel, varscan2
- HELB | c.482dup p.N161Kfs*3 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by pindel, varscan2
- HERC1 | c.12681dup p.S4228Ifs*7 | Frame Shift Ins (INS) | VAF 4/33 reads (12%) | called by mutect2, pindel, varscan2
- HERC1 | c.7432dup p.Q2478Pfs*13 | Frame Shift Ins (INS) | VAF 6/52 reads (12%) | called by mutect2, pindel, varscan2
- HLA-B | c.941dup p.L315Pfs*19 | Frame Shift Ins (INS) | VAF 6/79 reads (8%) | called by mutect2, pindel
- HPF1 | c.509dup p.K171Efs*4 | Frame Shift Ins (INS) | VAF 4/42 reads (10%) | called by pindel, varscan2
- HS3ST2 | c.442dup p.H148Pfs*4 | Frame Shift Ins (INS) | VAF 4/31 reads (13%) | called by mutect2, varscan2
- HUWE1 | c.4623G>C p.K1541N | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- ICAM1 | c.1033dup p.V345Gfs*108 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by pindel, varscan2
- IFNL1 | c.447dup p.L150Afs*49 | Frame Shift Ins (INS) | VAF 3/21 reads (14%) | called by mutect2, pindel
- IGLV11-55 | c.83_84insT p.L29Pfs*18 | Frame Shift Ins (INS) | VAF 3/20 reads (15%) | called by mutect2, pindel
- IL22RA1 | c.146dup p.D50Rfs*9 | Frame Shift Ins (INS) | VAF 6/54 reads (11%) | called by mutect2, pindel, varscan2
- INO80D | c.656dup p.L219Ffs*53 | Frame Shift Ins (INS) | VAF 7/43 reads (16%) | called by mutect2, pindel, varscan2
- IQGAP2 | c.4410dup p.K1471Qfs*18 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by mutect2, varscan2
- IRX2 | c.541dup p.A181Gfs*9 | Frame Shift Ins (INS) | VAF 4/24 reads (17%) | called by pindel, varscan2
- ISL1 | c.533dup p.E179Gfs*75 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by pindel, varscan2
- ITIH4 | c.826dup p.V276Gfs*5 | Frame Shift Ins (INS) | VAF 3/30 reads (10%) | called by mutect2, pindel
- ITIH6 | c.3565dup p.L1189Pfs*18 | Frame Shift Ins (INS) | VAF 3/27 reads (11%) | called by mutect2, pindel
- ITPKB | c.779dup p.I261Yfs*16 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | called by pindel, varscan2
- KANK2 | c.111dup p.Y38Lfs*15 | Frame Shift Ins (INS) | VAF 4/22 reads (18%) | called by pindel, varscan2
- KATNIP | c.2549dup p.A851Cfs*2 | Frame Shift Ins (INS) | VAF 5/41 reads (12%) | called by mutect2, pindel
- KBTBD4 | c.1357dup p.R453Pfs*6 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by pindel, varscan2
- KCNA3 | c.783dup p.E262Rfs*58 | Frame Shift Ins (INS) | VAF 4/39 reads (10%) | called by mutect2, pindel, varscan2
- KCNB1 | c.990dup p.L331Vfs*23 | Frame Shift Ins (INS) | VAF 3/33 reads (9%) | called by mutect2, pindel
- KCNC2 | c.120dup p.E41Rfs*212 | Frame Shift Ins (INS) | VAF 3/19 reads (16%) | called by mutect2, pindel
- KCNH2 | c.2299dup p.D767Gfs*37 | Frame Shift Ins (INS) | VAF 4/33 reads (12%) | called by mutect2, pindel, varscan2
- KCNK13 | c.1099dup p.L367Pfs*3 | Frame Shift Ins (INS) | VAF 3/32 reads (9%) | called by mutect2, pindel
- KIAA0825 | c.59dup p.F21Ifs*8 | Frame Shift Ins (INS) | VAF 3/27 reads (11%) | called by mutect2, pindel
- KIAA1109 | c.8424dup p.T2809Yfs*3 | Frame Shift Ins (INS) | VAF 4/37 reads (11%) | called by mutect2, pindel, varscan2
- KIAA1755 | c.2143dup p.H715Pfs*17 | Frame Shift Ins (INS) | VAF 5/38 reads (13%) | called by pindel, varscan2
- KMT2B | c.530dup p.A178Cfs*6 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by pindel, varscan2
- KMT2B | c.8079dup p.I2694Hfs*22 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by mutect2, pindel
- KMT2D | c.15496dup p.A5166Gfs*2 | Frame Shift Ins (INS) | VAF 3/26 reads (12%) | called by mutect2, pindel
- KRT222 | c.560dup p.Q188Tfs*4 | Frame Shift Ins (INS) | VAF 4/20 reads (20%) | called by mutect2, pindel, varscan2
- LAMB2 | c.1867dup p.L623Pfs*11 | Frame Shift Ins (INS) | VAF 3/26 reads (12%) | called by mutect2, pindel
- LIFR | c.2270dup p.G758Rfs*15 | Frame Shift Ins (INS) | VAF 3/29 reads (10%) | called by mutect2, pindel
- LMTK2 | c.1334dup p.I446Nfs*13 | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | called by mutect2, pindel, varscan2
- LRRC32 | c.1690dup p.R564Pfs*56 | Frame Shift Ins (INS) | VAF 3/28 reads (11%) | called by mutect2, pindel
- LRRC8D | c.1482dup p.L495Afs*4 | Frame Shift Ins (INS) | VAF 4/24 reads (17%) | called by mutect2, pindel
- LRRK2 | c.66dup p.L23Afs*86 | Frame Shift Ins (INS) | VAF 3/22 reads (14%) | called by mutect2, pindel
- LYPD2 | c.58+1dup p.X20_splice | Splice Site (INS) | VAF 4/42 reads (10%) | called by mutect2, varscan2
- MACF1 | c.20834dup p.N6945Kfs*36 (on ENST00000372915; = p.N4990Kfs*36 on NM_012090.5) | Frame Shift Ins (INS) | VAF 6/63 reads (10%) | called by mutect2, varscan2
- MARS1 | c.2372dup p.G792Rfs*17 | Frame Shift Ins (INS) | VAF 3/29 reads (10%) | called by mutect2, pindel
- MATN3 | c.1169-1_1169insC p.V390Afs*3 | Frame Shift Ins (INS) | VAF 3/23 reads (13%) | called by mutect2, pindel
- MBD6 | c.133dup p.S45Ffs*25 | Frame Shift Ins (INS) | VAF 3/35 reads (9%) | called by mutect2, pindel
- MCM2 | c.2198dup p.K734Efs*16 | Frame Shift Ins (INS) | VAF 6/44 reads (14%) | called by mutect2, varscan2
- MDGA2 | c.2305dup p.I769Nfs*4 (on ENST00000399232 / NM_001113498.2; = p.I471Nfs*4 on NM_182830.4) | Frame Shift Ins (INS) | VAF 4/39 reads (10%) | called by mutect2, pindel, varscan2
- MDN1 | c.3831_3832insG p.W1278Vfs*3 | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | called by mutect2, pindel
- MED13 | c.913dup p.C305Lfs*28 | Frame Shift Ins (INS) | VAF 5/46 reads (11%) | called by mutect2, varscan2
- MEGF10 | c.1044dup p.R349Afs*9 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | called by mutect2, pindel
- MEGF8 | c.3341dup p.C1114Wfs*25 (on ENST00000251268 / NM_001271938.2; = p.C1047Wfs*25 on NM_001410.3) | Frame Shift Ins (INS) | VAF 3/19 reads (16%) | called by mutect2, pindel
- MFHAS1 | c.2534dup p.A846Sfs*21 | Frame Shift Ins (INS) | VAF 4/41 reads (10%) | called by pindel, varscan2
- MINPP1 | c.777dup p.N260Efs*16 | Frame Shift Ins (INS) | VAF 3/25 reads (12%) | called by mutect2, pindel
- MLLT6 | c.847dup p.H283Pfs*11 | Frame Shift Ins (INS) | VAF 3/25 reads (12%) | called by mutect2, pindel
- MPEG1 | c.1606dup p.V536Gfs*81 | Frame Shift Ins (INS) | VAF 3/36 reads (8%) | called by mutect2, pindel
- MPP3 | c.439dup p.L147Pfs*36 | Frame Shift Ins (INS) | VAF 4/22 reads (18%) | called by pindel, varscan2
- MPP7 | c.960dup p.R321* | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by pindel, varscan2
- MROH1 | c.2860dup p.L954Pfs*49 | Frame Shift Ins (INS) | VAF 3/25 reads (12%) | called by mutect2, pindel
- MROH7 | c.2896dup p.L966Pfs*69 | Frame Shift Ins (INS) | VAF 6/56 reads (11%) | called by mutect2, varscan2
- MYC | c.670dup p.L224Pfs*19 (on ENST00000377970; = p.L239Pfs*19 on NM_002467.6) | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel
- MYO5B | c.2090+1dup p.X697_splice | Splice Site (INS) | VAF 6/50 reads (12%) | called by mutect2, varscan2
- MYO9B | c.172dup p.D58Gfs*92 | Frame Shift Ins (INS) | VAF 3/24 reads (13%) | called by mutect2, pindel
- N4BP2L2 | c.2177dup p.H727Afs*3 (on ENST00000674422; = p.H298Afs*3 on NM_033111.4) | Frame Shift Ins (INS) | VAF 5/45 reads (11%) | called by mutect2, pindel
- NAV2 | c.1791dup p.K598Efs*110 (on ENST00000396087 / NM_001244963.2; = p.K575Efs*110 on NM_145117.5) | Frame Shift Ins (INS) | VAF 4/39 reads (10%) | called by mutect2, pindel, varscan2
- NAV2 | c.5663A>G p.H1888R (on ENST00000396087 / NM_001244963.2; = p.H1829R on NM_145117.5) | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.649); called by mutect2, varscan2
- NCAM1 | c.1247dup p.L418Afs*64 (on ENST00000316851 / NM_181351.5; = p.L408Afs*64 on NM_000615.7) | Frame Shift Ins (INS) | VAF 4/39 reads (10%) | called by mutect2, pindel, varscan2
- NCOA6 | c.103dup p.D35Gfs*2 | Frame Shift Ins (INS) | VAF 4/44 reads (9%) | called by mutect2, pindel
- NDUFB8 | c.300dup p.W101Lfs*3 | Frame Shift Ins (INS) | VAF 3/26 reads (12%) | called by mutect2, pindel
- NDUFV3 | c.131dup p.Q45Sfs*20 (on ENST00000340344 / NM_001001503.2; = p.Q45Sfs*31 on NM_021075.4) | Frame Shift Ins (INS) | VAF 5/39 reads (13%) | called by mutect2, pindel, varscan2
- NEDD4 | c.670dup p.C224Lfs*2 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by mutect2, pindel, varscan2
- NEFH | c.1904dup p.E636Gfs*15 | Frame Shift Ins (INS) | VAF 6/40 reads (15%) | called by pindel, varscan2
- NLGN3 | c.295dup p.A99Gfs*72 (on ENST00000358741 / NM_181303.2; = p.A99Gfs*59 on NM_018977.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 3/35 reads (9%) | called by mutect2, pindel
- NLGN3 | c.1390dup p.R464Pfs*2 (on ENST00000358741 / NM_181303.2; = p.R444Pfs*2 on NM_018977.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 4/42 reads (10%) | called by mutect2, pindel
- NLGN4X | c.1300dup p.E434Gfs*13 | Frame Shift Ins (INS) | VAF 3/23 reads (13%) | called by mutect2, pindel
- NSD1 | c.7848dup p.L2617Vfs*66 | Frame Shift Ins (INS) | VAF 3/28 reads (11%) | called by mutect2, pindel
- NT5C1B | c.1576dup p.R526Pfs*14 (on ENST00000359846 / NM_001199086.2; = p.R466Pfs*14 on NM_033253.4) | Frame Shift Ins (INS) | VAF 6/52 reads (12%) | called by pindel, varscan2
- NTAQ1 | c.517dup p.M173Nfs*31 | Frame Shift Ins (INS) | VAF 4/44 reads (9%) | called by mutect2, pindel
- NUP107 | c.2092_2093insG p.K698Rfs*28 | Frame Shift Ins (INS) | VAF 3/35 reads (9%) | called by mutect2, pindel
- NUP210 | c.2830dup p.A944Gfs*17 | Frame Shift Ins (INS) | VAF 4/44 reads (9%) | called by mutect2, pindel
- NUP42 | c.759dup p.F254Ifs*41 | Frame Shift Ins (INS) | VAF 3/34 reads (9%) | called by mutect2, pindel
- OCA2 | c.1310C>G p.S437C | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- OFD1 | c.2225dup p.R744Kfs*6 | Frame Shift Ins (INS) | VAF 3/22 reads (14%) | called by mutect2, pindel
- OR5K4 | c.688T>A p.S230T | Missense Mutation (SNP) | VAF 53/194 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by mutect2, varscan2
- OTUB1 | c.293_294insG p.F98Lfs*10 | Frame Shift Ins (INS) | VAF 4/48 reads (8%) | called by mutect2, pindel
- PAX3 | c.1230dup p.A411Rfs*44 | Frame Shift Ins (INS) | VAF 4/42 reads (10%) | called by mutect2, pindel, varscan2
- PAXIP1 | c.970dup p.R324Kfs*20 | Frame Shift Ins (INS) | VAF 4/46 reads (9%) | called by mutect2, pindel
- PCDH11X | c.1189A>C p.T397P | Missense Mutation (SNP) | VAF 81/244 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by mutect2, varscan2
- PCDHAC1 | c.91dup p.E31Gfs*89 | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | called by pindel, varscan2
- PCDHB7 | c.208dup p.Q70Pfs*14 | Frame Shift Ins (INS) | VAF 5/44 reads (11%) | called by mutect2, varscan2
- PCDHGA10 | c.2210dup p.G738Rfs*53 | Frame Shift Ins (INS) | VAF 3/32 reads (9%) | called by mutect2, pindel
- PDE3A | c.633dup p.V212Rfs*8 | Frame Shift Ins (INS) | VAF 3/33 reads (9%) | called by mutect2, pindel
- PDGFRB | c.2259dup p.M754Hfs*24 | Frame Shift Ins (INS) | VAF 4/46 reads (9%) | called by mutect2, pindel
- PEAR1 | c.2530dup p.A844Gfs*7 | Frame Shift Ins (INS) | VAF 3/28 reads (11%) | called by mutect2, pindel
- PHF12 | c.660dup p.N221Efs*10 | Frame Shift Ins (INS) | VAF 3/20 reads (15%) | called by mutect2, pindel
- PHF21A | c.1691_1692insG p.E565Rfs*7 (on ENST00000418153 / NM_001101802.3; = p.E519Rfs*7 on NM_016621.5 and 5 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by mutect2, pindel
- PHYHIP | c.901dup p.E301Gfs*89 | Frame Shift Ins (INS) | VAF 6/64 reads (9%) | called by pindel, varscan2
- PIM2 | c.302dup p.L102Pfs*3 | Frame Shift Ins (INS) | VAF 3/23 reads (13%) | called by mutect2, pindel
- PLAAT4 | c.486dup p.T163Dfs*54 | Frame Shift Ins (INS) | VAF 5/47 reads (11%) | called by mutect2, pindel
- PLEKHG4 | c.2389C>G p.L797V | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- PMS2 | c.2275+1dup p.X759_splice | Splice Site (INS) | VAF 3/32 reads (9%) | called by mutect2, pindel
- PODXL2 | c.520dup p.E174Gfs*32 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by mutect2, varscan2
- POLE | c.5914_5915insC p.V1972Afs*87 | Frame Shift Ins (INS) | VAF 6/68 reads (9%) | called by mutect2, pindel*
- POLQ | c.171dup p.K58Qfs*6 | Frame Shift Ins (INS) | VAF 4/45 reads (9%) | called by mutect2, pindel
- POP1 | c.551dup p.C184Wfs*10 | Frame Shift Ins (INS) | VAF 3/35 reads (9%) | called by mutect2, pindel
- PPCDC | c.28dup p.A10Gfs*45 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel
- PPIG | c.1458dup p.S487Vfs*4 | Frame Shift Ins (INS) | VAF 4/43 reads (9%) | called by mutect2, pindel, varscan2
- PPP2R2A | c.1128dup p.I377Hfs*11 | Frame Shift Ins (INS) | VAF 4/39 reads (10%) | called by mutect2, pindel, varscan2
- PPTC7 | c.414dup p.A139Rfs*30 | Frame Shift Ins (INS) | VAF 3/22 reads (14%) | called by mutect2, pindel
- PRSS36 | c.1956dup p.S653Qfs*86 | Frame Shift Ins (INS) | VAF 4/46 reads (9%) | called by mutect2, pindel
- PRUNE2 | c.4808dup p.K1604Efs*6 | Frame Shift Ins (INS) | VAF 5/43 reads (12%) | called by mutect2, pindel, varscan2
- PSD | c.2091+1dup p.X697_splice | Splice Site (INS) | VAF 4/24 reads (17%) | called by mutect2, pindel
- PSD4 | c.822dup p.A275Cfs*8 | Frame Shift Ins (INS) | VAF 6/64 reads (9%) | called by mutect2, pindel
- PSMG3 | c.46dup p.V16Gfs*41 | Frame Shift Ins (INS) | VAF 3/22 reads (14%) | called by mutect2, pindel
- PTH1R | c.1353+1dup | Frame Shift Ins (INS) | VAF 4/31 reads (13%) | called by mutect2, pindel
- PTPN4 | c.2705dup p.F903Ifs*4 | Frame Shift Ins (INS) | VAF 3/19 reads (16%) | called by mutect2, pindel
- PTPRN2 | c.451dup p.L151Pfs*33 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by pindel, varscan2
- PUM2 | c.1610dup p.L538Ffs*20 | Frame Shift Ins (INS) | VAF 4/41 reads (10%) | called by mutect2, pindel, varscan2
- PXDN | c.2663dup p.M889Hfs*34 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by pindel, varscan2
- RABEPK | c.736dup p.H246Pfs*39 | Frame Shift Ins (INS) | VAF 7/60 reads (12%) | called by mutect2, pindel, varscan2
- RAP1GDS1 | c.574dup p.H192Pfs*17 (on ENST00000408927 / NM_001100427.2; = p.H193Pfs*17 on NM_021159.5) | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by mutect2, pindel, varscan2
- RASAL2 | c.3079dup p.E1027Gfs*22 | Frame Shift Ins (INS) | VAF 3/21 reads (14%) | called by mutect2, pindel
- RAX | c.338dup p.G114Rfs*37 | Frame Shift Ins (INS) | VAF 4/44 reads (9%) | called by mutect2, pindel
- RBM5 | c.854dup p.M285Ifs*20 | Frame Shift Ins (INS) | VAF 3/36 reads (8%) | called by mutect2, pindel
- RELN | c.10030A>C p.S3344R | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.968); called by mutect2, varscan2
- RIPK4 | c.2413dup p.H805Pfs*67 (on ENST00000352483; = p.H757Pfs*67 on NM_020639.3) | Frame Shift Ins (INS) | VAF 3/34 reads (9%) | called by mutect2, pindel
- RNF213 | c.2087dup p.V697Cfs*20 | Frame Shift Ins (INS) | VAF 6/42 reads (14%) | called by mutect2, varscan2
- RNF213 | c.7207dup p.I2403Nfs*29 | Frame Shift Ins (INS) | VAF 5/41 reads (12%) | called by mutect2, pindel, varscan2
- ROS1 | c.3089dup p.S1031Ifs*8 | Frame Shift Ins (INS) | VAF 6/61 reads (10%) | called by pindel, varscan2
- RPSA | c.181dup p.A61Gfs*9 | Frame Shift Ins (INS) | VAF 5/57 reads (9%) | called by mutect2, pindel
- RREB1 | c.978dup p.M327Hfs*30 | Frame Shift Ins (INS) | VAF 4/25 reads (16%) | called by mutect2, pindel
- RSL1D1 | c.747dup p.L250Tfs*7 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | called by mutect2, pindel
- RYR2 | c.11413dup p.L3805Pfs*5 | Frame Shift Ins (INS) | VAF 4/29 reads (14%) | called by mutect2, pindel
- SALL1 | c.2858dup p.S954Kfs*22 | Frame Shift Ins (INS) | VAF 5/46 reads (11%) | called by mutect2, varscan2
- SAMD14 | c.521dup p.P175Sfs*2 | Frame Shift Ins (INS) | VAF 3/21 reads (14%) | called by mutect2, pindel
- SAMM50 | c.794dup p.D265Efs*18 | Frame Shift Ins (INS) | VAF 3/24 reads (13%) | called by mutect2, pindel
- SARDH | c.1415dup p.H474Pfs*3 | Frame Shift Ins (INS) | VAF 4/22 reads (18%) | called by pindel, varscan2
- SCAPER | c.2718dup p.R907Afs*22 | Frame Shift Ins (INS) | VAF 4/39 reads (10%) | called by pindel, varscan2
- SCARA3 | c.1282dup p.V428Gfs*155 | Frame Shift Ins (INS) | VAF 3/27 reads (11%) | called by mutect2, pindel
- SEC14L5 | c.2077dup p.L693Pfs*69 | Frame Shift Ins (INS) | VAF 4/22 reads (18%) | called by mutect2, pindel
- SGK2 | c.453dup p.R152Afs*16 | Frame Shift Ins (INS) | VAF 6/49 reads (12%) | called by mutect2, pindel, varscan2
- SH3RF3 | c.1625dup p.P543Sfs*173 | Frame Shift Ins (INS) | VAF 5/40 reads (13%) | called by mutect2, pindel, varscan2
- SI | c.2257dup p.V753Gfs*7 | Frame Shift Ins (INS) | VAF 6/68 reads (9%) | called by pindel, varscan2
- SLC25A17 | c.655dup p.V219Gfs*18 | Frame Shift Ins (INS) | VAF 4/35 reads (11%) | called by pindel, varscan2
- SLC25A19 | c.616dup p.A206Gfs*10 | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | called by pindel, varscan2
- SLC34A2 | c.832-1dup p.X278_splice | Splice Site (INS) | VAF 3/29 reads (10%) | called by mutect2, pindel
- SLC4A3 | c.2368dup p.L790Pfs*70 | Frame Shift Ins (INS) | VAF 5/52 reads (10%) | called by mutect2, pindel
- SLC4A4 | c.2367dup p.L790Vfs*23 (on ENST00000264485 / NM_001098484.3; = p.L746Vfs*23 on NM_003759.4) | Frame Shift Ins (INS) | VAF 3/33 reads (9%) | called by mutect2, pindel
- SLC66A1 | c.840dup p.A281Rfs*6 | Frame Shift Ins (INS) | VAF 3/21 reads (14%) | called by mutect2, pindel
- SLC7A10 | c.547dup p.A183Gfs*78 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by pindel, varscan2
- SLCO5A1 | c.46G>T p.E16* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | called by mutect2, varscan2
- SMARCA4 | c.3608dup p.L1204Pfs*39 | Frame Shift Ins (INS) | VAF 3/33 reads (9%) | called by mutect2, pindel
- SMARCC2 | c.1738G>C p.D580H | Missense Mutation (SNP) | VAF 54/71 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- SMARCD1 | c.1327dup p.S443Kfs*12 | Frame Shift Ins (INS) | VAF 3/31 reads (10%) | called by mutect2, pindel
- SMCR8 | c.975dup p.C326Lfs*2 | Frame Shift Ins (INS) | VAF 3/24 reads (13%) | called by mutect2, pindel
- SNED1 | c.3934dup p.S1312Ffs*21 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by mutect2, varscan2
- SOGA3 | c.1377dup p.E460Rfs*9 | Frame Shift Ins (INS) | VAF 4/24 reads (17%) | called by mutect2, pindel
- SPATA13 | c.1727dup p.N576Kfs*117 | Frame Shift Ins (INS) | VAF 5/39 reads (13%) | called by mutect2, pindel, varscan2
- SPEG | c.2756dup p.A920Gfs*2 | Frame Shift Ins (INS) | VAF 4/41 reads (10%) | called by mutect2, pindel
- SPTA1 | c.3559dup p.V1187Gfs*8 | Frame Shift Ins (INS) | VAF 3/31 reads (10%) | called by mutect2, pindel
- SPTAN1 | c.3520-1G>C p.X1174_splice | Splice Site (SNP) | VAF 40/162 reads (25%) | called by mutect2, varscan2
- SPTB | c.1372dup p.E458Gfs*8 | Frame Shift Ins (INS) | VAF 3/29 reads (10%) | called by mutect2, pindel, varscan2
- SQLE | c.423dup p.L142Afs*12 | Frame Shift Ins (INS) | VAF 6/62 reads (10%) | called by mutect2, pindel, varscan2
- SRCAP | c.8235dup p.V2746Sfs*38 | Frame Shift Ins (INS) | VAF 4/39 reads (10%) | called by mutect2, pindel, varscan2
- SRPK2 | c.456_462del p.K153Qfs*3 | Frame Shift Del (DEL) | VAF 37/219 reads (17%) | called by pindel, varscan2
- SRRM1 | c.2413dup p.E805Gfs*19 | Frame Shift Ins (INS) | VAF 4/35 reads (11%) | called by mutect2, pindel, varscan2
- SRSF4 | c.945dup p.S316Efs*60 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | called by pindel, varscan2
- SSRP1 | c.1099dup p.V367Gfs*7 | Frame Shift Ins (INS) | VAF 4/20 reads (20%) | called by mutect2, pindel
- STAB2 | c.3747dup p.N1250Qfs*5 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | called by pindel, varscan2
- STAC2 | c.1052dup p.G352Rfs*38 | Frame Shift Ins (INS) | VAF 3/21 reads (14%) | called by mutect2, pindel
- STS | c.253dup p.R85Pfs*26 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by mutect2, varscan2
- SUDS3 | c.959dup p.V321Rfs*39 | Frame Shift Ins (INS) | VAF 3/32 reads (9%) | called by mutect2, pindel
- SYNPO2 | c.2709dup p.T904Hfs*23 | Frame Shift Ins (INS) | VAF 4/42 reads (10%) | called by pindel, varscan2
- TBCD | c.3249dup p.D1084Rfs*58 | Frame Shift Ins (INS) | VAF 4/41 reads (10%) | called by mutect2, pindel, varscan2
- TBL1X | c.1535dup p.S514Qfs*3 | Frame Shift Ins (INS) | VAF 6/65 reads (9%) | called by pindel, varscan2
- TCP11L1 | c.517dup p.A173Gfs*25 | Frame Shift Ins (INS) | VAF 5/56 reads (9%) | called by mutect2, pindel
- TDP2 | c.528dup p.G177Rfs*43 | Frame Shift Ins (INS) | VAF 5/48 reads (10%) | called by mutect2, pindel, varscan2
- TDRD1 | c.2684dup p.L895Ffs*8 | Frame Shift Ins (INS) | VAF 4/37 reads (11%) | called by mutect2, varscan2
- TEFM | c.141dup p.T48Yfs*4 | Frame Shift Ins (INS) | VAF 3/23 reads (13%) | called by mutect2, pindel
- TENT4B | c.1113dup p.T372Yfs*8 (on ENST00000561678 / NM_001365323.2; = p.T357Yfs*8 on NM_001040284.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 4/41 reads (10%) | called by mutect2, pindel
- TEX15 | c.2329dup p.I777Nfs*3 (on ENST00000256246; = p.I1160Nfs*3 on NM_001350162.2) | Frame Shift Ins (INS) | VAF 7/57 reads (12%) | called by mutect2, pindel
- THSD7A | c.625A>G p.T209A | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.392); called by mutect2, varscan2
- TIAM2 | c.1516G>C p.V506L | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by mutect2, varscan2
- TLK1 | c.809dup p.C270Wfs*11 | Frame Shift Ins (INS) | VAF 3/25 reads (12%) | called by mutect2, pindel
- TMEM141 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); called by muse, mutect2
- TMEM163 | c.490dup p.L164Pfs*13 | Frame Shift Ins (INS) | VAF 3/33 reads (9%) | called by mutect2, pindel
- TMEM63C | c.548dup p.L184Afs*6 | Frame Shift Ins (INS) | VAF 3/23 reads (13%) | called by mutect2, pindel
- TMEM68 | c.435dup p.I146Yfs*12 | Frame Shift Ins (INS) | VAF 4/18 reads (22%) | called by pindel, varscan2
- TMPRSS9 | c.916dup p.R306Pfs*21 (on ENST00000648592; = p.R272Pfs*21 on NM_182973.2) | Frame Shift Ins (INS) | VAF 3/33 reads (9%) | called by mutect2, pindel
- TNR | c.1582dup p.R528Pfs*84 | Frame Shift Ins (INS) | VAF 3/34 reads (9%) | called by mutect2, pindel
- TNRC6C | c.4598dup p.L1533Ffs*54 | Frame Shift Ins (INS) | VAF 3/25 reads (12%) | called by mutect2, pindel
- TPCN1 | c.1186dup p.L396Pfs*26 | Frame Shift Ins (INS) | VAF 3/28 reads (11%) | called by mutect2, pindel
- TRIM46 | c.1559_1560insG p.D520Efs*18 | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | called by mutect2, pindel
- TRMT2A | c.1765dup p.V589Gfs*26 | Frame Shift Ins (INS) | VAF 6/34 reads (18%) | called by mutect2, varscan2
- TROAP | c.219dup p.H74Afs*25 | Frame Shift Ins (INS) | VAF 6/52 reads (12%) | called by mutect2, varscan2
- TRPV1 | c.2035dup p.L679Pfs*7 | Frame Shift Ins (INS) | VAF 4/23 reads (17%) | called by mutect2, pindel, varscan2
- TTN | c.81770A>T p.N27257I (on ENST00000591111; = p.N19833I on NM_003319.4) | Missense Mutation (SNP) | VAF 96/180 reads (53%) | PolyPhen benign (0.189); called by mutect2, varscan2
- UBA2 | c.882dup p.N295Efs*8 | Frame Shift Ins (INS) | VAF 3/31 reads (10%) | called by mutect2, pindel
- URGCP | c.967dup p.E323Gfs*18 (on ENST00000453200 / NM_001077663.3; = p.E314Gfs*18 on NM_017920.4) | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by mutect2, pindel, varscan2
- USP54 | c.2856dup p.K954Efs*7 | Frame Shift Ins (INS) | VAF 4/44 reads (9%) | called by mutect2, pindel
- VN1R1 | c.296dup p.F100Lfs*2 | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | called by pindel, varscan2
- VNN1 | c.67dup p.D23Gfs*9 | Frame Shift Ins (INS) | VAF 5/46 reads (11%) | called by mutect2, pindel
- WASF1 | c.440dup p.L148Sfs*12 | Frame Shift Ins (INS) | VAF 3/23 reads (13%) | called by mutect2, pindel
- WNT5B | c.692dup p.C231Wfs*85 | Frame Shift Ins (INS) | VAF 4/29 reads (14%) | called by mutect2, pindel
- XRCC1 | c.458dup p.D154Rfs*4 | Frame Shift Ins (INS) | VAF 5/41 reads (12%) | called by mutect2, pindel, varscan2
- YLPM1 | c.1889C>T p.P630L | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.923); called by mutect2, varscan2
- YOD1 | c.430dup p.E144Gfs*21 | Frame Shift Ins (INS) | VAF 5/52 reads (10%) | called by pindel, varscan2
- ZBTB9 | c.757dup p.L253Pfs*14 | Frame Shift Ins (INS) | VAF 3/31 reads (10%) | called by mutect2, pindel
- ZCCHC7 | c.983T>G p.L328R | Missense Mutation (SNP) | VAF 82/196 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- ZFHX3 | c.7479dup p.P2495Tfs*39 | Frame Shift Ins (INS) | VAF 5/37 reads (14%) | called by mutect2, varscan2
- ZFYVE1 | c.920dup p.L308Ffs*13 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by mutect2, pindel, varscan2
- ZGRF1 | c.4007dup p.E1337Rfs*9 | Frame Shift Ins (INS) | VAF 5/48 reads (10%) | called by mutect2, varscan2
- ZNF26 | c.452dup p.D151Efs*2 | Frame Shift Ins (INS) | VAF 5/38 reads (13%) | called by mutect2, pindel, varscan2
- ZNF366 | c.457dup p.E153Gfs*4 | Frame Shift Ins (INS) | VAF 5/44 reads (11%) | called by mutect2, pindel, varscan2
- ZNF471 | c.1418A>T p.H473L | Missense Mutation (SNP) | VAF 68/206 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- ZNF536 | c.1973dup p.E660Rfs*11 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by pindel, varscan2
- ZNF692 | c.879dup p.S294Qfs*16 | Frame Shift Ins (INS) | VAF 3/29 reads (10%) | called by mutect2, pindel
- ZP3 | c.385dup p.V129Gfs*4 (on ENST00000394857 / NM_001110354.2; = p.V78Gfs*4 on NM_007155.6) | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, varscan2
- ZWILCH | c.1276dup p.D426Gfs*57 | Frame Shift Ins (INS) | VAF 5/44 reads (11%) | called by pindel, varscan2
- ZZEF1 | c.8611dup p.L2871Pfs*14 | Frame Shift Ins (INS) | VAF 4/23 reads (17%) | called by pindel, varscan2
- ACAN | c.843C>T p.A281= | Silent (SNP) | VAF 7/11 reads (64%) | called by muse, mutect2, varscan2
- FLNA | c.381G>A p.K127= | Silent (SNP) | VAF 9/12 reads (75%) | catalogued as CM1212812; called by muse, mutect2, varscan2
- IQUB | c.1071C>T p.F357= | Silent (SNP) | VAF 33/119 reads (28%) | catalogued as rs201226714; called by mutect2, varscan2
- KNSTRN | c.201G>A p.R67= | Silent (SNP) | VAF 18/33 reads (55%) | called by muse, mutect2, varscan2
- MID1IP1 | c.297C>T p.N99= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as COSV61230441; called by muse, varscan2
- OR10G7 | c.15C>G p.T5= | Silent (SNP) | VAF 36/104 reads (35%) | called by mutect2, varscan2
- PCDH17 | c.768T>G p.A256= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100931473; called by muse, varscan2
- RSAD1 | c.1302A>G p.R434= | Silent (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- SIK2 | c.2298A>G p.P766= | Silent (SNP) | VAF 60/85 reads (71%) | called by mutect2, varscan2
- WDR6 | c.123G>A p.V41= | Silent (SNP) | VAF 60/138 reads (43%) | catalogued as rs1192786345; called by mutect2, varscan2
- AC016747.4 | n.528dup | RNA (INS) | VAF 4/34 reads (12%) | called by pindel, varscan2
- BIRC5 | c.*2dup | 3'UTR (INS) | VAF 3/24 reads (13%) | called by mutect2, pindel
- C8orf86 | n.486G>C | RNA (SNP) | VAF 30/58 reads (52%) | called by muse, varscan2
- CEP295 | chr11:93735187 ins C | 3'Flank (INS) | VAF 4/35 reads (11%) | called by mutect2, pindel
- CTNNAL1 | c.519+592A>T | Intron (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- CUTA | chr6:33418116 ins C | 5'Flank (INS) | VAF 3/29 reads (10%) | called by mutect2, pindel
- DNAH8 | chr6:38723120 C>T | 5'Flank (SNP) | VAF 14/155 reads (9%) | catalogued as rs954540376, COSV100545902, COSV100547542; called by mutect2, varscan2
- FMN1 | c.2044-2298dup | Intron (INS) | VAF 8/78 reads (10%) | called by mutect2, varscan2
- LRRC27 | chr10:132331658 ins C | 5'Flank (INS) | VAF 3/21 reads (14%) | called by mutect2, pindel
- MARCHF1 | c.-322-85572dup | Intron (INS) | VAF 3/31 reads (10%) | called by mutect2, pindel, varscan2
- NACA | c.70+3152dup | Intron (INS) | VAF 4/40 reads (10%) | called by pindel, varscan2
- NDUFV3 | c.170-5262dup | Intron (INS) | VAF 3/31 reads (10%) | called by mutect2, pindel
- PAPPA2 | c.2431+16T>G | Intron (SNP) | VAF 26/241 reads (11%) | catalogued as rs1204447549; called by mutect2, varscan2
- SMAP2 | c.-1dup | 5'UTR (INS) | VAF 4/41 reads (10%) | called by mutect2, pindel
- WASF4P | n.965dup | RNA (INS) | VAF 4/40 reads (10%) | catalogued as rs1556875956; called by pindel, varscan2
- ZNF688 | c.-591dup | 5'UTR (INS) | VAF 6/48 reads (13%) | catalogued as rs1465516557; called by mutect2, pindel
